FM case AD12753 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/f0e22fa3-f4eb-4608-82b6-84a82b8ec0d4

Female, 85.8 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the stomach; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
